Somatic mutation profile of tumor specimen TCGA-69-7980-01A (aliquot TCGA-69-7980-01A-11D-2184-08) from TCGA case TCGA-69-7980, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 70.0 years (25,583 days).
Specimen TCGA-69-7980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0e451e5-6912-415e-8e45-747f229dff5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7980-10A (Blood Derived Normal), aliquot TCGA-69-7980-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aef0b9f8-8760-458e-80ad-54c7264d3eb3

The open-access MAF lists 876 somatic variants for this specimen: 677 protein-altering or splice-affecting, 184 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 571, Silent 184, Nonsense Mutation 41, Splice Site 24, Frame Shift Del 22, Intron 6, Splice Region 6, Frame Shift Ins 6, Translation Start Site 4, 3'Flank 3, RNA 3, In Frame Ins 2.

Variants (750 of 876; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554386687, COSV51661795, COSV51663139; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 28/35 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- OTC | c.663+1G>T p.X221_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | catalogued as rs68170503, CD0910724, CS961653, CS971835, COSV50003592; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 14/128 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTH1R | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398122843, CM114714, CS982335, COSV57317229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 44/86 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52678014, COSV52747111, COSV52839912, COSV53772942; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 52/94 reads (55%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.4059T>G p.D1353E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59384446, COSV59390915; called by muse, mutect2
- ABCA4 | c.2751C>A p.F917L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV64676521; called by muse, mutect2, varscan2
- ABCA6 | c.1437-2A>T p.X479_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV52643081; called by muse, mutect2, varscan2
- ABCA7 | c.924G>C p.M308I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV54035327; called by muse, mutect2, varscan2
- ABCA9 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV60629329; called by muse, mutect2, varscan2
- ABCB5 | c.1978G>C p.D660H (on ENST00000404938 / NM_001163941.2; = p.D215H on NM_178559.6) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as COSV51717387; called by muse, mutect2, varscan2
- ABT1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51292342; called by muse, mutect2, varscan2
- ACAN | c.2848G>A p.G950R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV61366826; called by muse, varscan2
- ACE2 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53026813; called by muse, mutect2, varscan2
- ACTC1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.948); catalogued as COSV51760745; called by muse, mutect2, varscan2
- ACTN1 | c.37A>G p.M13V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs774738700, COSV51995890; called by muse, mutect2, varscan2
- ADAM17 | c.371A>T p.D124V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV60401132; called by muse, mutect2
- ADAM20 | c.1708G>T p.G570* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV56456113; called by muse, mutect2, varscan2
- ADAM33 | c.1165A>G p.S389G | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100597839; called by muse, mutect2, varscan2
- ADAM33 | c.1164C>A p.C388* | Nonsense Mutation (SNP) | VAF 25/35 reads (71%) | catalogued as COSV100597842; called by muse, mutect2, varscan2
- ADAMTS12 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 91/153 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61273768; called by muse, mutect2, varscan2
- ADAMTS3 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778535799, COSV54398884; called by muse, mutect2
- ADAMTS4 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.259); catalogued as COSV63488447; called by muse, mutect2, varscan2
- ADCY10 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.961); catalogued as COSV63243782; called by muse, mutect2, varscan2
- ADGRB3 | c.2463G>C p.L821F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as COSV65412975; called by muse, mutect2, varscan2
- ADGRE1 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51679408; called by muse, mutect2, varscan2
- ADGRF4 | c.1895C>A p.T632K | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV51951903, COSV51956008; called by muse, mutect2, varscan2
- ADGRG4 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV54963883; called by muse, mutect2, varscan2
- ADGRG5 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV61084199; called by muse, mutect2
- AFF2 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV54001726; called by muse, mutect2, varscan2
- AGAP3 | c.2444G>T p.R815L (on ENST00000622464; = p.R851L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as COSV52548719; called by muse, mutect2, varscan2
- AGO2 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55050957; called by muse, mutect2, varscan2
- AKAP6 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV55227198; called by muse, mutect2, varscan2
- AKR1E2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs772663485, COSV53631417, COSV53631769; called by muse, mutect2, varscan2
- ALPK2 | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV64495717; called by muse, mutect2, varscan2
- ALPK2 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64495725; called by muse, mutect2, varscan2
- ALPP | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67397569; called by muse, mutect2, varscan2
- AMDHD1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV57139934; called by muse, mutect2, varscan2
- ANGPT1 | c.948T>A p.N316K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52450587; called by muse, mutect2, varscan2
- ANGPTL1 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52367787; called by muse, mutect2, varscan2
- ANKH | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV52481177, COSV52484817; called by muse, mutect2, varscan2
- ANKRD11 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56368549; called by muse, mutect2, varscan2
- ANKRD12 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV50839833; called by muse, mutect2
- ANKRD34B | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV58614375; called by muse, mutect2, varscan2
- ANKS1B | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV61367644; called by muse, mutect2, varscan2
- ANO6 | c.1975G>T p.G659C | Missense Mutation (SNP) | VAF 114/155 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57662842, COSV57666051; called by muse, mutect2, varscan2
- ANP32A | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); catalogued as COSV51189832; called by muse, mutect2, varscan2
- AP1B1 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58022023; called by muse, mutect2, varscan2
- AP4E1 | c.2230G>T p.A744S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55919250; called by muse, mutect2
- AP4E1 | c.2384G>T p.R795M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99956547; called by muse, mutect2, varscan2
- APEX2 | c.960G>C p.Q320H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV58192669; called by muse, mutect2, varscan2
- ARHGAP15 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV54509110, COSV54514150; called by muse, mutect2, varscan2
- ARHGEF11 | c.2729G>T p.R910L | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); catalogued as COSV59357082; called by muse, mutect2, varscan2
- ARID1B | c.4458G>C p.M1486I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); catalogued as rs1391970327, COSV51675099; called by muse, mutect2, varscan2
- ASAH2 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV61484220; called by muse, mutect2, varscan2
- ASB5 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774259355, COSV56673280; called by muse, mutect2, varscan2
- ASTN2 | c.3644G>C p.G1215A (on ENST00000313400 / NM_001365069.1; = p.G1164A on NM_014010.5) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56000526, COSV56011941; called by muse, mutect2
- ATAD2 | c.2981G>T p.R994I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54885114; called by muse, mutect2, varscan2
- ATF7IP | c.3393+1G>A p.X1131_splice | Splice Site (SNP) | VAF 40/59 reads (68%) | catalogued as rs372005685; called by muse, mutect2, varscan2
- ATP2B2 | c.2023G>T p.D675Y (on ENST00000352432; = p.D641Y on NM_001683.5) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59504891; called by muse, mutect2, varscan2
- ATP2B2 | c.1711C>A p.Q571K (on ENST00000352432; = p.Q537K on NM_001683.5) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as COSV59504910; called by muse, mutect2, varscan2
- ATP2B4 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58182260; called by muse, mutect2
- ATP8A2 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54969747; called by muse, mutect2, varscan2
- BMPR2 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV65812548; called by muse, mutect2, varscan2
- BMPR2 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV65812554; called by muse, mutect2, varscan2
- BNIP1 | c.41A>C p.Q14P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs574543486, COSV51571683; called by muse, mutect2, varscan2
- BNIP5 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV71325780; called by muse, mutect2, varscan2
- BTN1A1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs771506326, COSV55069027; called by muse, mutect2, varscan2
- C14orf180 | c.117C>G p.D39E | Missense Mutation (SNP) | VAF 2/24 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV59557654; called by muse, mutect2
- C1QA | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213084266, COSV65889202; called by muse, mutect2
- C1QA | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373684177, COSV101009457; called by muse, mutect2
- C1QL3 | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.739); catalogued as COSV54349277; called by muse, mutect2, varscan2
- C2orf80 | c.207G>T p.L69= | Splice Region (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100378373, COSV58015784; called by muse, mutect2, varscan2
- C8B | c.1055del p.G352Afs*9 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs1557734608, COSV64779540; called by pindel, varscan2
- CA10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53364706; called by muse, mutect2, varscan2
- CACNA1E | c.6578C>G p.S2193C (on ENST00000367573 / NM_001205293.3; = p.S2150C on NM_000721.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV62400052, COSV62411592; called by muse, mutect2, varscan2
- CACNB2 | c.769C>T p.H257Y (on ENST00000324631 / NM_201596.3; = p.H202Y on NM_000724.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV99994136, COSV99995448; called by muse, mutect2, varscan2
- CALB2 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226194; called by muse, mutect2, varscan2
- CAMTA1 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.572); catalogued as rs368952127; called by muse, mutect2, varscan2
- CBL | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50653855; called by muse, mutect2, varscan2
- CBLN1 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54654850; called by muse, mutect2
- CCDC116 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as rs143471938; called by muse, mutect2, varscan2
- CCDC190 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63363393; called by muse, mutect2, varscan2
- CCIN | c.1195C>G p.R399G | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.496); catalogued as COSV58725324; called by muse, mutect2, varscan2
- CCKAR | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs770226902, COSV55163198; called by muse, mutect2, varscan2
- CCL11 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as COSV59925525, COSV59925532; called by muse, mutect2, varscan2
- CCSER2 | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56507500, COSV56510013; called by muse, mutect2, varscan2
- CCT6B | c.1102A>T p.N368Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58487678; called by muse, mutect2, varscan2
- CD226 | c.458A>T p.Q153L | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV54614992; called by muse, mutect2, varscan2
- CD300E | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206028324, COSV60791376; called by muse, mutect2, varscan2
- CD300LF | c.497T>A p.L166* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV56898466; called by muse, mutect2, varscan2
- CD6 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100532956; called by muse, mutect2, varscan2
- CD6 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs779299811, COSV100532959; called by muse, mutect2, varscan2
- CD8A | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV99374374; called by muse, mutect2, varscan2
- CDH18 | c.1306A>T p.N436Y | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV56949758; called by muse, mutect2, varscan2
- CDH7 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59891881; called by muse, mutect2, varscan2
- CDH7 | c.2253C>G p.I751M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV59891897; called by muse, mutect2
- CDH9 | c.1843G>C p.A615P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50384520, COSV99144061; called by muse, mutect2, varscan2
- CDKL4 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66510719; called by muse, mutect2, varscan2
- CELSR3 | c.4644G>C p.Q1548H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51089101; called by muse, mutect2
- CEP120 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60267579; called by muse, mutect2, varscan2
- CETN1 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59121814, COSV59121981; called by muse, mutect2, varscan2
- CFAP47 | c.5039A>C p.K1680T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV100545267; called by muse, mutect2, varscan2
- CFAP54 | c.8195T>G p.M2732R | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV61574255; called by muse, mutect2, varscan2
- CFAP61 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 75/98 reads (77%) | catalogued as COSV55642046; called by muse, mutect2, varscan2
- CFAP61 | c.3422G>C p.S1141T | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV55642066; called by muse, mutect2, varscan2
- CFC1 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as COSV52090768; called by muse, varscan2
- CFH | c.3657G>T p.W1219C | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.51); catalogued as COSV66411718; called by muse, mutect2, varscan2
- CHRM2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446523872, COSV57777879; called by muse, mutect2, varscan2
- CHRM2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV57775055, COSV57781065; called by muse, mutect2, varscan2
- CHRNA1 | c.980T>C p.M327T (on ENST00000261007 / NM_001039523.3; = p.M302T on NM_000079.4) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV53684491; called by muse, mutect2, varscan2
- CHRNA3 | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV55139945; called by muse, mutect2, varscan2
- CHRNG | c.1249+2T>G p.X417_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV67315872; called by muse, mutect2, varscan2
- CIC | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 62/112 reads (55%) | catalogued as COSV50555408, COSV50645444; called by muse, mutect2, varscan2
- CKAP2 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV51623886; called by mutect2, varscan2
- CLDN12 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.325); catalogued as COSV55307732; called by muse, mutect2, varscan2
- CLEC4G | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV61003938; called by muse, mutect2, varscan2
- CLPX | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV55645997; called by muse, mutect2, varscan2
- CLSTN2 | c.1199T>A p.I400N | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV71723825; called by muse, mutect2, varscan2
- CLSTN2 | c.2270G>T p.W757L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.386); catalogued as COSV101515668; called by muse, mutect2, varscan2
- CLSTN2 | c.2271G>T p.W757C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV101515669; called by muse, mutect2, varscan2
- CMYA5 | c.5774G>T p.R1925M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV71408608; called by muse, mutect2
- CNGA4 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56413823; called by muse, mutect2, varscan2
- CNOT1 | c.6756G>C p.Q2252H | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55320773; called by muse, mutect2, varscan2
- CNOT1 | c.6187A>G p.M2063V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs750989114, COSV55320787; called by muse, mutect2, varscan2
- CNTN4 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316109477, COSV100639121, COSV61878444; called by muse, mutect2, varscan2
- COL19A1 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100506107, COSV59576876; called by muse, mutect2, varscan2
- COL19A1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100506108, COSV59574899; called by muse, mutect2, varscan2
- COL19A1 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs755925878, COSV59583048; called by muse, mutect2, varscan2
- COL27A1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV61929777; called by muse, mutect2, varscan2
- COL3A1 | c.4286T>C p.F1429S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as CD1412752, COSV58594472; called by muse, mutect2, varscan2
- COL4A4 | c.1495A>G p.M499V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61635101; called by muse, mutect2, varscan2
- COL5A2 | c.3328G>C p.G1110R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880015, COSV66413325; called by muse, mutect2, varscan2
- COL6A3 | c.6092G>T p.G2031V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV55103029; called by muse, mutect2, varscan2
- COL6A3 | c.4956G>T p.R1652S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55103044, COSV55112525; called by muse, mutect2, varscan2
- COLGALT2 | c.1313A>T p.D438V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62300282; called by muse, mutect2, varscan2
- CORIN | c.2294T>C p.L765S | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV56696966; called by muse, mutect2
- COX4I1 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV53666468; called by muse, mutect2, varscan2
- CPEB1 | c.766G>T p.D256Y (on ENST00000617958; = p.D196Y on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55618589, COSV55620785; called by muse, mutect2, varscan2
- CPT1C | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV54918800, COSV99773133; called by muse, mutect2, varscan2
- CREB3L3 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50249569; called by muse, mutect2, varscan2
- CRISP3 | c.691G>A p.D231N (on ENST00000371159 / NM_001368123.1; = p.D213N on NM_006061.4) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs996891773, COSV53819037; called by muse, mutect2, varscan2
- CRISPLD1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51551794; called by muse, mutect2, varscan2
- CROCC | c.2095C>A p.L699M | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100978168; called by muse, mutect2
- CRTAM | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57070578; called by muse, mutect2, varscan2
- CRTAP | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV58014715; called by muse, mutect2, varscan2
- CRTC2 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57845081; called by muse, mutect2, varscan2
- CRYBA2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1284922338, COSV55386920, COSV55387252; called by muse, mutect2, varscan2
- CSGALNACT1 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59981880; called by muse, mutect2, varscan2
- CSMD2 | c.7853C>A p.A2618D | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); catalogued as COSV53946654, COSV99595562; called by muse, mutect2, varscan2
- CSMD3 | c.938C>G p.P313R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775310571, COSV52276914; called by muse, mutect2, varscan2
- CTDP1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as rs1007276458, COSV50007729; called by muse, mutect2
- CTNNA1 | c.2436G>A p.V812= | Splice Region (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57079462; called by muse, mutect2, varscan2
- CUX2 | c.1933A>G p.T645A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55643520; called by muse, mutect2, varscan2
- CYLD | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 22/208 reads (11%) | catalogued as COSV100282383, COSV61096646; called by muse, mutect2, varscan2
- CYLD | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as COSV100282386, COSV61097439; called by muse, mutect2, varscan2
- DAB1 | c.208-1G>T p.X70_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV59734549; called by muse, mutect2
- DAGLB | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99765798; called by muse, mutect2
- DAZAP1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV51835488; called by muse, mutect2, varscan2
- DCAF11 | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 29/165 reads (18%) | catalogued as COSV58110294; called by muse, mutect2, varscan2
- DCAF4L2 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100150671, COSV60476277, COSV60478817; called by muse, mutect2, varscan2
- DDR2 | c.1361T>A p.F454Y | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63373400; called by muse, mutect2, varscan2
- DDR2 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100906466; called by muse, mutect2, varscan2
- DDX18 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54308469; called by muse, mutect2
- DDX60 | c.4534G>T p.V1512L | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV101190415; called by muse, mutect2, varscan2
- DDX60 | c.4534-1G>A p.X1512_splice | Splice Site (SNP) | VAF 37/56 reads (66%) | catalogued as COSV101190417; called by muse, mutect2, varscan2
- DGKI | c.1092T>A p.F364L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV55968446; called by muse, mutect2, varscan2
- DHRS3 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs147390617, COSV66108397; called by muse, mutect2, varscan2
- DLC1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); catalogued as COSV52320748; called by muse, mutect2, varscan2
- DLK1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV57992975; called by muse, mutect2, varscan2
- DMD | c.10247G>T p.W3416L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58939470; called by muse, mutect2, varscan2
- DMD | c.8690C>A p.A2897D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58939518; called by muse, mutect2, varscan2
- DMD | c.2933G>T p.R978I | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV63780379; called by muse, mutect2, varscan2
- DMD | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV55892923; called by muse, mutect2, varscan2
- DMP1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs1282694158, COSV56821724; called by muse, mutect2
- DMRT1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66523558; called by muse, mutect2, varscan2
- DMRT3 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV51907354; called by muse, mutect2, varscan2
- DNAH3 | c.3379G>A p.A1127T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as COSV54529031, COSV54542538; called by muse, mutect2, varscan2
- DNAH5 | c.1923G>T p.M641I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as COSV54244458; called by muse, mutect2, varscan2
- DNAH7 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1463168531, COSV56753234, COSV56779367; called by muse, mutect2, varscan2
- DNAH8 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as COSV59471109; called by muse, mutect2
- DNMT3L | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54265575; called by muse, mutect2, varscan2
- DNTT | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV64523527; called by muse, mutect2, varscan2
- DOCK10 | c.6328C>A p.Q2110K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV51423933; called by muse, mutect2, varscan2
- DOCK11 | c.2516A>T p.Q839L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV52245398; called by muse, mutect2, varscan2
- DPAGT1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62615011; called by muse, mutect2, varscan2
- DPPA2 | c.281A>T p.K94M | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV72118260; called by muse, mutect2, varscan2
- DRD2 | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV60761522; called by muse, mutect2, varscan2
- DRD2 | c.947A>C p.H316P | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as rs1182082677, COSV60761560; called by muse, varscan2
- DROSHA | c.1709G>T p.R570I | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV60780625; called by muse, mutect2, varscan2
- DSN1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV65519629; called by muse, mutect2, varscan2
- DTNA | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV52019401; called by muse, mutect2, varscan2
- DUSP22 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60529907, COSV60530704; called by muse, mutect2
- DYSF | c.5150G>C p.R1717P | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV50465253, COSV50523892; called by muse, mutect2, varscan2
- E2F2 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | catalogued as COSV62276689; called by muse, mutect2, varscan2
- EBF3 | c.1519C>T p.P507S (on ENST00000355311 / NM_001375392.1; = p.P498S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV62479596; called by muse, mutect2, varscan2
- ECEL1 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV58813802; called by muse, mutect2, varscan2
- EFCC1 | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 81/122 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1423634610, COSV71402103; called by muse, mutect2, varscan2
- ELF3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.989); catalogued as COSV62837284; called by muse, mutect2, varscan2
- ELOA | c.596A>C p.D199A | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV69311039; called by muse, mutect2, varscan2
- EMILIN2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV54426295; called by muse, mutect2, varscan2
- ENPP6 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57067137, COSV57071017; called by muse, mutect2, varscan2
- EPB41L3 | c.3202T>A p.S1068T | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59464143; called by muse, mutect2
- EPHA5 | c.2298+1G>A p.X766_splice | Splice Site (SNP) | VAF 61/87 reads (70%) | catalogued as COSV56664919; called by muse, mutect2, varscan2
- EPS8L3 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62610305; called by muse, mutect2, varscan2
- ERBB4 | c.2604G>C p.L868F | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61465696; called by muse, mutect2, varscan2
- ERBB4 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53568566, COSV53600039; called by muse, mutect2, varscan2
- ERN2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV56836534; called by muse, mutect2, varscan2
- ESRP1 | c.1726T>C p.S576P | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV64411889; called by muse, mutect2, varscan2
- ESX1 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV65424960; called by muse, varscan2
- EVI2B | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 62/373 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV104401417, COSV58364863; called by muse, mutect2, varscan2
- F13A1 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as rs778745917, COSV53564786; called by muse, mutect2, varscan2
- FAM135B | c.4125C>G p.N1375K | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52745646, COSV99421847; called by muse, mutect2, varscan2
- FAM209B | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100990949, COSV64915048; called by muse, mutect2, varscan2
- FAM47C | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV63729321; called by muse, varscan2
- FAM53C | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53512571; called by muse, mutect2, varscan2
- FAT4 | c.4097G>T p.S1366I | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67890738, COSV67896057; called by muse, mutect2, varscan2
- FCN3 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV54642211, COSV54642253; called by muse, mutect2, varscan2
- FERMT2 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs141887548, COSV58408710; called by muse, mutect2, varscan2
- FILIP1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 25/222 reads (11%) | catalogued as rs905027708, COSV52725481; called by muse, mutect2, varscan2
- FKBP8 | c.574G>T p.A192S (on ENST00000222308 / NM_001308373.2; = p.A193S on NM_012181.5) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.555); catalogued as COSV55893581; called by muse, mutect2, varscan2
- FMNL1 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58958458; called by muse, mutect2, varscan2
- FNDC1 | c.2993C>A p.P998H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs920820048, COSV51945301; called by muse, mutect2, varscan2
- FRMD5 | c.1117C>G p.H373D | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV68724495; called by muse, mutect2, varscan2
- FRMPD1 | c.3920C>A p.S1307Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV66702065; called by mutect2, varscan2
- FSCB | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV61219220; called by muse, mutect2, varscan2
- FSTL5 | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV60219022; called by muse, varscan2
- GABRA6 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50889371; called by muse, mutect2, varscan2
- GABRG1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as rs769209641, COSV54955110; called by muse, mutect2, varscan2
- GCC2 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV59178941; called by muse, mutect2, varscan2
- GCG | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV64961994, COSV64962310; called by muse, mutect2, varscan2
- GCNA | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV65467843; called by muse, mutect2, varscan2
- GEMIN7 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54320524; called by muse, mutect2
- GIGYF2 | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV65252435; called by muse, mutect2, varscan2
- GJC2 | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100812984, COSV64513213; called by muse, mutect2, varscan2
- GLI3 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV67893346; called by muse, mutect2, varscan2
- GLRA2 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV54345861; called by muse, mutect2, varscan2
- GLRX3 | c.825-2A>T p.X275_splice | Splice Site (SNP) | VAF 44/75 reads (59%) | catalogued as COSV58693943; called by muse, mutect2, varscan2
- GP2 | c.1556-1G>T p.X519_splice (on ENST00000381362 / NM_001007240.3; = p.X516_splice on NM_001502.4) | Splice Site (SNP) | VAF 45/69 reads (65%) | catalogued as COSV100221441, COSV56895297; called by muse, mutect2, varscan2
- GPR15 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52520491; called by muse, mutect2
- GPR89A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58260176; called by muse, mutect2, varscan2
- GRB2 | c.453A>G p.I151M | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57306513; called by muse, mutect2, varscan2
- GRIA4 | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV56913034; called by muse, mutect2, varscan2
- GRIN2A | c.1702G>T p.V568F | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58050969; called by muse, mutect2, varscan2
- H2AC6 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV58416030, COSV58417289; called by muse, mutect2, varscan2
- HAND2 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64018821; called by muse, mutect2, varscan2
- HDAC6 | c.2301G>T p.M767I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1557029280, COSV100490752; called by muse, mutect2, varscan2
- HEATR5B | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV51857111; called by muse, mutect2, varscan2
- HEATR6 | c.2629G>C p.A877P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51745398, COSV99482278; called by muse, mutect2, varscan2
- HECW1 | c.2945G>T p.C982F | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV67837307; called by muse, mutect2, varscan2
- HEMGN | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs770329844, COSV52327722; called by muse, mutect2, varscan2
- HEPH | c.1780A>T p.N594Y (on ENST00000343002; = p.N327Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV57969650; called by muse, mutect2, varscan2
- HGD | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52200565; called by muse, mutect2
- HGFAC | c.1309G>T p.V437F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV101237748; called by muse, mutect2, varscan2
- HGS | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs761456662, COSV61269739; called by muse, mutect2, varscan2
- HHIPL2 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58566922; called by muse, mutect2, varscan2
- HIVEP1 | c.7135C>G p.H2379D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV65104128; called by muse, mutect2, varscan2
- HK3 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52837659; called by muse, mutect2, varscan2
- HNRNPH2 | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54510294; called by muse, mutect2, varscan2
- HRNR | c.5762C>T p.S1921F | Missense Mutation (SNP) | VAF 210/2424 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV64261282; called by muse, mutect2
- HS3ST2 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54466750; called by muse, mutect2, varscan2
- HS3ST5 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs751584987, COSV57138721, COSV57149650; called by muse, mutect2, varscan2
- HUWE1 | c.4067C>A p.P1356H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53359419; called by muse, mutect2, varscan2
- HUWE1 | c.425G>C p.S142T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV53359436; called by muse, mutect2
- IGDCC4 | c.2117A>T p.Q706L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV61538679; called by muse, mutect2, varscan2
- IGLV4-60 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs554418977, COSV101135214, COSV66503697, COSV66503734; called by muse, mutect2, varscan2
- IKBKB | c.1944G>T p.E648D | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.379); catalogued as COSV60599093; called by muse, mutect2, varscan2
- IL1RAPL1 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56288510; called by muse, mutect2, varscan2
- IL27 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV60493060; called by muse, mutect2, varscan2
- IMPG2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV51983467; called by muse, mutect2, varscan2
- INCENP | c.2405C>G p.T802S (on ENST00000394818 / NM_001040694.2; = p.T798S on NM_020238.3) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV53919508; called by muse, mutect2, varscan2
- INHBA | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.278); catalogued as COSV54220880; called by muse, mutect2
- INPP5B | c.2494G>C p.E832Q (on ENST00000373023; = p.E752Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65962450; called by muse, mutect2, varscan2
- INSRR | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100947501, COSV63876281; called by muse, mutect2, varscan2
- IQCN | c.3380T>G p.F1127C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV62748497; called by muse, mutect2, varscan2
- IQGAP3 | c.3336G>C p.Q1112H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63253772; called by muse, mutect2, varscan2
- IRS1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs1024227751, COSV59333264, COSV59334285; called by muse, mutect2, varscan2
- ITGAD | c.2907G>T p.W969C | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1391624499, COSV54932545; called by muse, mutect2, varscan2
- ITGBL1 | c.869-2A>T p.X290_splice | Splice Site (SNP) | VAF 47/133 reads (35%) | catalogued as COSV66010870; called by muse, mutect2, varscan2
- JAK2 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV67649648; called by muse, mutect2, varscan2
- KAT2B | c.1188C>A p.Y396* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV55433020; called by muse, mutect2, varscan2
- KCNA4 | c.1913C>G p.T638R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.07); catalogued as COSV60254993, COSV60256317; called by muse, mutect2, varscan2
- KCNAB3 | c.286+1G>C p.X96_splice | Splice Site (SNP) | VAF 28/209 reads (13%) | catalogued as rs776051168, COSV58050865; called by muse, mutect2, varscan2
- KCNG4 | c.671C>G p.A224G | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57585488; called by muse, mutect2, varscan2
- KCNH7 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 28/171 reads (16%) | catalogued as COSV59808500; called by muse, mutect2, varscan2
- KCNMA1 | c.2948C>A p.P983Q (on ENST00000286628 / NM_001161352.2; = p.P925Q on NM_002247.4) | Missense Mutation (SNP) | VAF 141/219 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV54274373, COSV54297445; called by muse, mutect2, varscan2
- KCNT1 | c.2463C>T p.N821= (on ENST00000488444; = p.N840= on NM_020822.3) | Splice Region (SNP) | VAF 23/38 reads (61%) | catalogued as COSV53696578, COSV53708152; called by muse, mutect2, varscan2
- KDM3B | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as COSV58693856; called by muse, mutect2, varscan2
- KHDRBS3 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63422632; called by muse, mutect2, varscan2
- KIAA1522 | c.1751C>G p.S584* (on ENST00000373480 / NM_001198972.2; = p.S643* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 25/232 reads (11%) | catalogued as COSV53866970; called by muse, mutect2, varscan2
- KIF2B | c.783C>A p.N261K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV52128606, COSV52133257; called by muse, mutect2, varscan2
- KIF4A | c.2741C>A p.T914K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV65545002; called by muse, mutect2, varscan2
- KIR3DL2 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV54394425; called by muse, mutect2, varscan2
- KLHL18 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99230792; called by muse, mutect2, varscan2
- KMT2B | c.5034G>C p.K1678N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55866839; called by muse, mutect2
- KRT25 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56446130; called by muse, mutect2, varscan2
- KRT36 | c.1397C>A p.P466Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV60204366; called by muse, mutect2, varscan2
- KRT36 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV60204420; called by muse, mutect2, varscan2
- KRTAP10-2 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV59974225; called by muse, mutect2, varscan2
- KYNU | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933139; called by muse, mutect2, varscan2
- LAMA1 | c.3526C>A p.Q1176K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV67533438; called by muse, mutect2
- LAMA2 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs768602307, COSV70352590; called by muse, mutect2, varscan2
- LAMA2 | c.8620A>T p.K2874* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV70352979; called by muse, mutect2, varscan2
- LAMA3 | c.1178G>C p.C393S | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58076118; called by muse, mutect2, varscan2
- LARP4B | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV60223035; called by muse, mutect2, varscan2
- LBX2 | c.515C>T p.P172L (on ENST00000377566 / NM_001282430.2; = p.P168L on NM_001009812.2) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52036718; called by muse, mutect2, varscan2
- LDLRAD4 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV63341523; called by muse, mutect2, varscan2
- LIPC | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | catalogued as rs1408986383, COSV54422061; called by muse, mutect2
- LIPG | c.1312del p.R438Afs*7 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs1295163816; called by mutect2, pindel, varscan2
- LPA | c.3355C>A p.P1119T | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60307977; called by muse, mutect2, varscan2
- LRFN1 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV50441957; called by muse, mutect2
- LRFN5 | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53270032; called by muse, mutect2, varscan2
- LRFN5 | c.1784G>C p.G595A | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV53270035; called by muse, mutect2, varscan2
- LRP1 | c.13060G>A p.V4354I | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54521194; called by muse, mutect2, varscan2
- LRP1B | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV67258949; called by muse, mutect2, varscan2
- LRRC36 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373608861, COSV99339077; called by muse, mutect2, varscan2
- LRRC47 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65563370; called by muse, mutect2, varscan2
- LRRN1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60015551; called by muse, mutect2, varscan2
- LRRN1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60014763; called by muse, mutect2, varscan2
- MAGEC2 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.425); catalogued as COSV56000031; called by muse, mutect2
- MAGEC3 | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV68924143; called by muse, mutect2
- MAN2B2 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV53455805; called by muse, mutect2, varscan2
- MASP1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51459001, COSV51460493; called by muse, mutect2, varscan2
- MCF2 | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58489729, COSV58492311; called by muse, mutect2, varscan2
- MCMDC2 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV58039393; called by muse, mutect2, varscan2
- MED12 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as rs771092011, COSV61359518; called by muse, mutect2, varscan2
- MEDAG | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as COSV100995248, COSV66851017; called by muse, mutect2
- MEP1B | c.1703T>A p.L568Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52499444; called by muse, mutect2, varscan2
- MERTK | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54933948; called by muse, mutect2, varscan2
- MID1 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100452244, COSV58197978; called by muse, mutect2, varscan2
- MID1 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV104397924, COSV58197988; called by muse, mutect2, varscan2
- MID2 | c.1651A>T p.N551Y | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV53312761; called by muse, mutect2, varscan2
- MMAB | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57170928; called by muse, mutect2, varscan2
- MMP2 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 20/180 reads (11%) | catalogued as CM161169, COSV54604104; called by muse, mutect2, varscan2
- MMP20 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52777499; called by muse, mutect2, varscan2
- MMRN1 | c.1979G>T p.R660I | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV53341308; called by muse, mutect2, varscan2
- MN1 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.602); catalogued as rs1342065664, COSV56560998; called by muse, mutect2, varscan2
- MNDA | c.1118A>C p.Q373P | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV63740740, COSV63741747; called by muse, mutect2
- MRPL22 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54559170; called by muse, mutect2, varscan2
- MSLN | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53505181; called by muse, mutect2
- MTNR1B | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99925081; called by muse, mutect2, varscan2
- MTNR1B | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV57065140, COSV99925086; called by muse, mutect2, varscan2
- MTOR | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV63876273; called by muse, mutect2, varscan2
- MTOR | c.1607A>C p.Q536P | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63876280; called by muse, mutect2, varscan2
- MTX2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as rs1167310733, COSV50889033; called by muse, mutect2, varscan2
- MUC17 | c.12874+1G>T p.X4292_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV60299155; called by muse, mutect2, varscan2
- MUC5AC | c.14136C>G p.F4712L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.149); catalogued as COSV100611626, COSV64369898; called by muse, mutect2
- MXRA5 | c.5480G>T p.G1827V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV54245712; called by muse, mutect2, varscan2
- MXRA8 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV58511465; called by muse, mutect2, varscan2
- MYCN | c.1351C>G p.Q451E | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV55260515; called by muse, mutect2, varscan2
- MYH11 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55564625; called by muse, mutect2
- MYH8 | c.4937A>G p.Y1646C | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV67970466; called by muse, mutect2
- MYO18B | c.3209G>T p.G1070V | Missense Mutation (SNP) | VAF 102/161 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV59144442; called by muse, mutect2, varscan2
- MYO3A | c.4359G>T p.Q1453H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV56331026, COSV56343461; called by muse, mutect2, varscan2
- NAGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376933189, COSV67170192; ClinVar: uncertain significance; called by muse, mutect2
- NBAS | c.3412G>T p.A1138S | Missense Mutation (SNP) | VAF 94/162 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733321; called by muse, mutect2, varscan2
- NBEA | c.6504G>T p.K2168N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59811611; called by muse, mutect2, varscan2
- NBPF1 | c.2045A>T p.Q682L | Missense Mutation (SNP) | VAF 32/630 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV55328277; called by muse, mutect2
- NCAN | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs200250416, COSV53047964; called by muse, mutect2, varscan2
- NCAPG2 | c.1855A>G p.M619V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV51990695; called by muse, mutect2, varscan2
- NCF2 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as COSV62316428; called by mutect2, varscan2
- NCSTN | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV54190560; called by muse, mutect2, varscan2
- NDC80 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1420480492, COSV55249286; called by muse, mutect2, varscan2
- NDST4 | c.217A>C p.T73P | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52131806; called by muse, mutect2, varscan2
- NEB | c.8964G>T p.L2988F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51446357; called by muse, mutect2
- NEB | c.7291G>C p.E2431Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM064140, COSV51446391; called by muse, mutect2, varscan2
- NEDD4 | c.2795G>T p.G932V (on ENST00000508342 / NM_001284338.1; = p.G513V on NM_006154.4) | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59065261; called by muse, mutect2, varscan2
- NEK8 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV52047698; called by muse, mutect2, varscan2
- NEUROD1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.119); catalogued as COSV54550623; called by muse, mutect2, varscan2
- NFATC2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV65359633; called by muse, mutect2, varscan2
- NFATC4 | c.2024del p.R675Pfs*12 | Frame Shift Del (DEL) | VAF 58/220 reads (26%) | catalogued as COSV51596838; called by mutect2, pindel, varscan2
- NFRKB | c.4G>A p.D2N (on ENST00000446488 / NM_001143835.2; = p.D15N on NM_006165.3) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as COSV58759857; called by muse, mutect2, varscan2
- NID2 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53501012; called by muse, mutect2, varscan2
- NIPAL1 | c.1151A>T p.N384I | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV55007454; called by muse, mutect2, varscan2
- NKX2-5 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV61299826; called by muse, mutect2, varscan2
- NLGN4X | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52031205; called by muse, mutect2
- NLRP1 | c.1391A>C p.Q464P | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52574580; called by muse, mutect2, varscan2
- NME8 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV52254170; called by muse, mutect2, varscan2
- NMRAL1 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV52059195, COSV52060886; called by muse, varscan2
- NMRAL1 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1395640136, COSV52060896; called by muse, varscan2
- NOL6 | c.2486G>C p.R829T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV53044811; called by muse, mutect2
- NRROS | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV60746209, COSV60747215; called by muse, mutect2, varscan2
- NT5C1A | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV52495886; called by muse, mutect2, varscan2
- NUP205 | c.5149G>T p.G1717* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV53664254; called by muse, mutect2, varscan2
- NUP210 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 52/117 reads (44%) | catalogued as COSV54411687; called by muse, mutect2, varscan2
- NUP98 | c.533T>G p.V178G | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV61436837; called by muse, mutect2, varscan2
- NXN | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 79/88 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61099340; called by muse, mutect2, varscan2
- NYAP2 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.5); catalogued as COSV56013562; called by muse, mutect2, varscan2
- ODAM | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV68573331; called by muse, mutect2, varscan2
- OGDH | c.2920C>T p.R974W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); catalogued as rs755783802, COSV56055198; called by muse, mutect2, varscan2
- OR10AG1 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56634260; called by muse, mutect2, varscan2
- OR10C1 | c.371A>G p.Y124C (on ENST00000622521; = p.Y122C on NM_013941.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV65823735; called by muse, mutect2, varscan2
- OR11H1 | c.623C>A p.S208* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99421708, COSV99421741; called by muse, mutect2, varscan2
- OR2M7 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.71); catalogued as COSV58740120; called by muse, mutect2, varscan2
- OR2T10 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV57897880; called by muse, mutect2, varscan2
- OR2T12 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58776878; called by muse, mutect2, varscan2
- OR4L1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371358020; called by muse, mutect2, varscan2
- OR51B6 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66512993, COSV66513691; called by muse, mutect2, varscan2
- OR51T1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355098872, COSV59027364; called by muse, mutect2, varscan2
- OR52E4 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1315307621, COSV57624454; called by muse, mutect2, varscan2
- OR5F1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV53548060; called by muse, mutect2, varscan2
- OR5H1 | c.905C>G p.T302R | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63403206; called by muse, mutect2
- OR5L2 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV65723527, COSV65724863; called by muse, mutect2, varscan2
- OR5T2 | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV57590505; called by muse, mutect2
- OR6B1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68770485; called by muse, mutect2, varscan2
- OR6C2 | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV59516649; called by muse, mutect2
- OR6T1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 34/52 reads (65%) | catalogued as COSV58308861; called by muse, mutect2, varscan2
- OR8I2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56169707, COSV56169741; called by muse, mutect2, varscan2
- OR8I2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV56169726, COSV56170425; called by muse, mutect2, varscan2
- OSBPL3 | c.2386G>C p.D796H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57660899; called by muse, mutect2, varscan2
- OTOF | c.4417G>T p.G1473C (on ENST00000272371 / NM_194248.3; = p.G706C on NM_004802.4) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs371051158, CM1310659, COSV55514348; called by muse, mutect2, varscan2
- OTOP2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs1239732606, COSV58883184; called by muse, mutect2, varscan2
- OTP | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60568561; called by muse, mutect2, varscan2
- P2RY8 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67177995; called by muse, mutect2, varscan2
- PAGE1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as rs1265031213, COSV65998524; called by muse, mutect2, varscan2
- PAN2 | c.3433C>T p.Q1145* (on ENST00000425394 / NM_001127460.3; = p.Q1141* on NM_014871.5) | Nonsense Mutation (SNP) | VAF 24/203 reads (12%) | catalogued as COSV56264853, COSV56264939; called by muse, mutect2, varscan2
- PAX6 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53795087; called by muse, mutect2, varscan2
- PCBP2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63729606; called by muse, mutect2
- PCDHA13 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53843927, COSV53864050; called by muse, mutect2, varscan2
- PCDHB4 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.491); catalogued as COSV52025621; called by muse, mutect2, varscan2
- PCDHGA5 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.223); catalogued as rs969188576, COSV53908808; called by muse, mutect2, varscan2
- PCDHGB1 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54006107; called by muse, mutect2, varscan2
- PCLO | c.5378G>T p.R1793M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV61657149, COSV61661924; called by muse, mutect2
- PCLO | c.5376G>T p.Q1792H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61657161; called by muse, mutect2
- PDCD11 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV63934898; called by muse, mutect2, varscan2
- PDGFRA | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs747257877, COSV57271887; called by muse, mutect2, varscan2
- PDPK1 | c.1657G>C p.A553P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51912123, COSV51914153; called by muse, mutect2, varscan2
- PDZRN3 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55211474; called by muse, mutect2, varscan2
- PDZRN4 | c.2035G>C p.E679Q (on ENST00000402685 / NM_001164595.2; = p.E421Q on NM_013377.4) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs775748827, COSV54212107; called by muse, mutect2, varscan2
- PGAP4 | c.906G>C p.M302I | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV66387190, COSV66388227; called by muse, mutect2, varscan2
- PHF23 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.587); catalogued as rs922356318, COSV50038492, COSV99138550; called by muse, mutect2, varscan2
- PHGDH | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.142); catalogued as COSV65572065; called by muse, mutect2, varscan2
- PHLDB3 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52671505; called by muse, mutect2, varscan2
- PIGL | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV56687188; called by muse, mutect2, varscan2
- PIH1D2 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV54776124; called by muse, mutect2, varscan2
- PINX1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59110564; called by muse, mutect2, varscan2
- PITX1 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as rs775755663, COSV54762797; called by muse, mutect2, varscan2
- PKHD1 | c.8082C>A p.S2694R | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV61890053; called by muse, mutect2, varscan2
- PLA2G4A | c.905C>A p.T302K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV66555815; called by muse, mutect2, varscan2
- PLA2G7 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV51264218; called by muse, mutect2, varscan2
- PLCB1 | c.317T>A p.V106E | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV62062859; called by muse, mutect2, varscan2
- PLCB2 | c.3195G>T p.K1065N | Missense Mutation (SNP) | VAF 152/265 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53036811; called by muse, mutect2, varscan2
- PLCXD2 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1249589129, COSV67341775; called by muse, mutect2, varscan2
- PLEKHH1 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100232704, COSV100233033; called by muse, mutect2, varscan2
- PLSCR1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61013479; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1341-1G>A p.X447_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as rs758998223, COSV65049298; called by muse, mutect2, varscan2
- PNMA5 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62626086; called by muse, mutect2
- POLA1 | c.689-2A>T p.X230_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV66889576; called by muse, mutect2, varscan2
- POMGNT1 | c.1902G>T p.K634N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | PolyPhen benign (0.034); catalogued as rs1399465959, COSV64340597; called by muse, mutect2, varscan2
- POU2F2 | c.875G>T p.G292V (on ENST00000526816 / NM_001207025.3; = p.G276V on NM_002698.5) | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV60765803; called by muse, mutect2, varscan2
- POU2F2 | c.610G>T p.E204* (on ENST00000526816 / NM_001207025.3; = p.E188* on NM_002698.5) | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV60765820; called by muse, mutect2, varscan2
- PPID | c.84A>T p.R28= | Splice Region (SNP) | VAF 36/46 reads (78%) | catalogued as rs1305691320, COSV56988811; called by muse, mutect2, varscan2
- PRDM14 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV52574759; called by muse, mutect2, varscan2
- PRDX1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as rs765714807, COSV53114205; called by muse, mutect2, varscan2
- PRMT6 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV63656212; called by muse, mutect2, varscan2
- PROKR1 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs775396423, COSV58138692; called by muse, mutect2, varscan2
- PRRT3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); catalogued as COSV55978278; called by muse, mutect2, varscan2
- PRSS57 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs778932822, COSV100249725, COSV61386576; called by muse, mutect2, varscan2
- PSG4 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1343764508, COSV54935475; called by muse, mutect2, varscan2
- PSMD3 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52859156; called by muse, mutect2, varscan2
- PTCHD1 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65062223; called by muse, mutect2, varscan2
- PTGER3 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60695886; called by muse, mutect2, varscan2
- PTPRN | c.1908G>T p.M636I | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV55351122; called by muse, mutect2, varscan2
- PTPRS | c.4025G>C p.R1342T | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53632131; called by muse, mutect2
- PYGO1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as rs777622851, COSV57349559; called by muse, mutect2, varscan2
- QARS1 | c.876+1G>A p.X292_splice | Splice Site (SNP) | VAF 32/74 reads (43%) | catalogued as COSV60275849; called by muse, mutect2, varscan2
- QRICH2 | c.4921A>G p.S1641G | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53156637; called by muse, mutect2, varscan2
- R3HDML | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99407114; called by muse, mutect2, varscan2
- RAB27A | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1197622697, COSV61017331; called by muse, mutect2, varscan2
- RAD54L | c.36G>C p.K12N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV64336779; called by muse, mutect2, varscan2
- RALYL | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72824224; called by muse, mutect2, varscan2
- RAPGEF1 | c.2123A>G p.D708G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); catalogued as COSV64701465; called by muse, mutect2, varscan2
- RAPGEF6 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV57253475; called by muse, mutect2, varscan2
- RASAL2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.903); catalogued as COSV62720250; called by muse, mutect2, varscan2
- RASL11B | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs1182540556, COSV50535709; called by muse, mutect2, varscan2
- RBM46 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV55981091; called by muse, mutect2
- RCL1 | c.818A>C p.E273A | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67754336; called by muse, mutect2, varscan2
- REG1A | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52069344, COSV52069971; called by muse, mutect2, varscan2
- REL | c.535+1G>T p.X179_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | catalogued as COSV54362359, COSV54366495; called by muse, mutect2, varscan2
- RELN | c.7442G>A p.C2481Y | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59026052; called by muse, mutect2, varscan2
- RGS11 | c.872C>A p.A291D (on ENST00000397770 / NM_183337.3; = p.A270D on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV51453642; called by muse, mutect2, varscan2
- RGS14 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779184156, COSV68771802; called by muse, mutect2, varscan2
- RGS2 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV52459568; called by muse, mutect2, varscan2
- RIPOR1 | c.1910C>A p.T637N (on ENST00000379312 / NM_001193522.2; = p.T633N on NM_024519.4) | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV50245803; called by muse, mutect2, varscan2
- RIPPLY2 | c.96-1G>T p.X32_splice | Splice Site (SNP) | VAF 12/16 reads (75%) | catalogued as COSV63762944; called by muse, mutect2, varscan2
- RNF220 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 95/494 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV62408608; called by muse, mutect2, varscan2
- ROBO1 | c.1483G>T p.V495F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as COSV101458618; called by muse, mutect2, varscan2
- ROBO3 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67300997; called by muse, mutect2, varscan2
- RP1L1 | c.5505A>G p.I1835M | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV66758793; called by muse, mutect2, varscan2
- RPL13A | c.156G>A p.L52= | Splice Region (SNP) | VAF 7/76 reads (9%) | catalogued as COSV52620213; called by muse, mutect2
- RPL28 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs1175839786, COSV59805669; called by muse, mutect2, varscan2
- RRAGB | c.1121G>C p.R374P (on ENST00000262850 / NM_016656.4; = p.R346P on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53331095, COSV99469611; called by muse, mutect2
- RTL5 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101030024; called by muse, mutect2, varscan2
- RYR2 | c.7876G>C p.G2626R | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63705290, COSV63711507; called by muse, mutect2, varscan2
- RYR2 | c.12364G>T p.A4122S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100769669; called by muse, mutect2
- SALL2 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.575); catalogued as rs778734087, COSV58105197; called by muse, mutect2, varscan2
- SCML4 | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV64637273; called by muse, mutect2, varscan2
- SCRIB | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57586748, COSV57591843; called by muse, mutect2, varscan2
- SEC31A | c.3223A>G p.M1075V (on ENST00000355196 / NM_001318120.1; = p.M1036V on NM_016211.4) | Missense Mutation (SNP) | VAF 101/133 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52349821; called by muse, mutect2, varscan2
- SELENON | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs758344508, COSV62525944; called by muse, mutect2, varscan2
- SEMA3E | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.539); catalogued as COSV57103483; called by muse, mutect2, varscan2
- SEMA6D | c.998T>A p.M333K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60381968; called by muse, varscan2
- SERPINB7 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60534744, COSV60535263; called by muse, mutect2, varscan2
- SERPINE2 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51459360; called by muse, mutect2, varscan2
- SHC3 | c.1017C>A p.H339Q | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV65440153; called by muse, mutect2, varscan2
- SHPRH | c.1372G>T p.G458* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51615519; called by muse, mutect2, varscan2
- SHROOM3 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199533144, COSV56032308; called by muse, mutect2, varscan2
- SIGLEC12 | c.1361C>A p.S454Y (on ENST00000291707 / NM_053003.4; = p.S336Y on NM_033329.2) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52460508, COSV52463954; called by muse, mutect2, varscan2
- SIGLEC15 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV67181383; called by muse, mutect2
- SLC12A2 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | catalogued as COSV52472108, COSV52474944; called by muse, mutect2, varscan2
- SLC12A2 | c.1779G>T p.M593I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as COSV52474950; called by muse, varscan2
- SLC13A4 | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV62462444; called by muse, mutect2
- SLC17A7 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV55549147; called by muse, mutect2, varscan2
- SLC17A8 | c.1386G>T p.M462I | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV60125846; called by muse, mutect2, varscan2
- SLC26A7 | c.756A>T p.K252N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV52601527; called by muse, mutect2, varscan2
- SLC38A3 | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as COSV68844124; called by muse, mutect2, varscan2
- SLC41A1 | c.359T>C p.L120S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65651134; called by muse, mutect2, varscan2
- SLC4A3 | c.3576G>T p.R1192S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV56096498; called by muse, mutect2, varscan2
- SLC5A7 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50898425; called by muse, mutect2, varscan2
- SLC7A4 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100298669; called by muse, mutect2, varscan2
- SLC7A4 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100298670; called by muse, mutect2, varscan2
- SLC8A3 | c.981C>G p.H327Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV63525152; called by muse, mutect2, varscan2
- SLCO1B3 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 119/145 reads (82%) | catalogued as COSV53943829, COSV53946131; called by muse, mutect2, varscan2
- SLCO2A1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV60483718; called by muse, mutect2, varscan2
- SLFN5 | c.841del p.E282Kfs*34 | Frame Shift Del (DEL) | VAF 27/193 reads (14%) | catalogued as COSV55483629; called by mutect2, pindel, varscan2
- SLITRK5 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs533532510, COSV61521319, COSV61525109; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2, varscan2
- SLK | c.3180G>C p.L1060F | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59828072; called by muse, mutect2, varscan2
- SMC4 | c.3658G>A p.E1220K | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59088199; called by muse, mutect2, varscan2
- SNRNP70 | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55506743; called by muse, mutect2, varscan2
- SNTG1 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV52463398; called by muse, mutect2, varscan2
- SOX12 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61258832; called by muse, mutect2, varscan2
- SPAG17 | c.3589C>A p.P1197T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.295); catalogued as COSV60465098; called by muse, mutect2, varscan2
- SPARC | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50559955; called by muse, mutect2, varscan2
- SPATS1 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV55822437, COSV99913323; called by muse, mutect2
- SPP1 | c.488T>C p.V163A (on ENST00000395080 / NM_001040058.2; = p.V149A on NM_000582.2) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52952480; called by muse, mutect2, varscan2
- SPRR2G | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 27/115 reads (23%) | PolyPhen benign (0.395); catalogued as COSV64203311; called by muse, mutect2, varscan2
- SPTY2D1 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60474961; called by muse, mutect2, varscan2
- SRGAP1 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV61901732; called by muse, mutect2, varscan2
- SSB | c.20A>T p.N7I | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV53629934; called by muse, mutect2, varscan2
- SSBP3 | c.507+1G>T p.X169_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV58889189; called by muse, mutect2, varscan2
- ST6GAL2 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 50/91 reads (55%) | PolyPhen benign (0.026); catalogued as COSV62416652, COSV62417460, COSV62417694; called by muse, mutect2, varscan2
- STK11IP | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs775443446, COSV55253926; called by muse, mutect2, varscan2
- STK39 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63595773; called by muse, mutect2, varscan2
- STRIP2 | c.1995C>G p.I665M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50807129; called by muse, mutect2, varscan2
- SULF2 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs549518880, COSV63414827, COSV63419062; called by muse, mutect2, varscan2
- SULT1E1 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.12); catalogued as COSV56948310; called by muse, mutect2, varscan2
- SV2B | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV57701299; called by muse, mutect2
- SYN3 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV60513993; called by muse, mutect2, varscan2
- SYT13 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as COSV50076042; called by muse, mutect2, varscan2
- SYT2 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66142759; called by muse, mutect2, varscan2
- TADA1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV63310519; called by muse, mutect2, varscan2
- TAF1L | c.4928C>G p.A1643G | Missense Mutation (SNP) | VAF 132/173 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV54266869; called by muse, mutect2, varscan2
- TANC1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV55091671; called by muse, mutect2, varscan2
- TBC1D14 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63391785; called by muse, mutect2
- TECPR1 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV101130430; called by muse, mutect2, varscan2
- TENM1 | c.4400C>A p.A1467D | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64439757; called by muse, mutect2, varscan2
- TET1 | c.3286G>C p.E1096Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV65385754; called by muse, mutect2, varscan2
- TEX15 | c.2912A>G p.E971G (on ENST00000256246; = p.E1354G on NM_001350162.2) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56351726; called by muse, mutect2, varscan2
- TEX15 | c.1102G>A p.G368R (on ENST00000256246; = p.G751R on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1220844847, COSV56351738, COSV99822358; called by mutect2, varscan2
- TINAG | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52513389; called by muse, mutect2, varscan2
- TMC3 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759792425, COSV100845890; called by muse, mutect2, varscan2
- TMC3 | c.1701C>A p.N567K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100845891; called by muse, mutect2, varscan2
- TMCC2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.239); catalogued as COSV63665991; called by muse, mutect2, varscan2
- TMEM71 | c.677-1G>A p.X226_splice (on ENST00000523829 / NM_001382398.1; = p.X207_splice on NM_144649.3) | Splice Site (SNP) | VAF 23/87 reads (26%) | catalogued as COSV63458754; called by muse, mutect2, varscan2
- TMPRSS11E | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV59520618; called by muse, varscan2
- TMTC3 | c.1537-1G>C p.X513_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | catalogued as COSV57125714; called by muse, mutect2, varscan2
- TNKS2 | c.3254A>G p.K1085R | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV65416482; called by muse, mutect2, varscan2
- TPD52 | c.255+1G>T p.X85_splice (on ENST00000379097 / NM_001025252.3; = p.X45_splice on NM_005079.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/70 reads (26%) | catalogued as COSV66951519; called by muse, mutect2, varscan2
- TRAF6 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV61923356; called by muse, mutect2, varscan2
- TRANK1 | c.5460G>T p.Q1820H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as COSV57160617; called by muse, mutect2, varscan2
- TRAT1 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55468428, COSV55470286; called by muse, mutect2, varscan2
- TRHDE | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV53859513; called by muse, mutect2, varscan2
- TRIML1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as rs771144257, COSV60196226; called by muse, mutect2, varscan2
- TRIOBP | c.526A>T p.R176W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV60382682; called by mutect2, varscan2
- TRIP11 | c.2521A>T p.N841Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV50947649; called by muse, mutect2, varscan2
- TRPC4 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV59011688; called by muse, mutect2, varscan2
- TRPM1 | c.3264G>T p.Q1088H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV56639770; called by muse, mutect2, varscan2
- TRPM1 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV56633065; called by muse, mutect2, varscan2
- TRPM6 | c.5451C>G p.I1817M | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV62519572; called by muse, mutect2, varscan2
- TRPS1 | c.1877T>G p.V626G (on ENST00000220888 / NM_001330599.2; = p.V639G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV55255896; called by muse, mutect2, varscan2
- TSACC | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV64086822; called by muse, mutect2
- TSC22D4 | c.623G>C p.R208P | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs192378539, COSV55725060; called by muse, mutect2, varscan2
- TSPEAR | c.1608G>C p.E536D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1485267034, COSV59974219; called by muse, mutect2, varscan2
- TSR1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99280055; called by muse, mutect2
- TTC21B | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54633470; called by muse, mutect2
- TTC29 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV57282415; called by muse, mutect2, varscan2
- TTC37 | c.2735A>T p.D912V | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1184514201, COSV62456265; called by muse, mutect2, varscan2
- TTN | c.87200C>T p.S29067F (on ENST00000591111; = p.S21643F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/220 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV60258732; called by muse, mutect2, varscan2
- TTN | c.71131A>G p.T23711A (on ENST00000591111; = p.T16287A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | PolyPhen benign (0.179); catalogued as COSV60258779; called by muse, mutect2
- TTN | c.71129G>A p.W23710* (on ENST00000591111; = p.W16286* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV60258811; called by muse, mutect2
- TTN | c.13565C>A p.P4522H (on ENST00000591111; = p.P3595H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | PolyPhen benign (0.247); catalogued as rs1478089830, COSV60258875; called by muse, mutect2, varscan2
- TTN | c.7474C>G p.Q2492E (on ENST00000591111; = p.Q2446E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | PolyPhen benign (0.066); catalogued as rs1223970193, COSV60258888; called by muse, mutect2, varscan2
- TUBA3D | c.1177C>G p.H393D | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV58312913; called by muse, mutect2, varscan2
- TUBB4A | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51162396; called by muse, mutect2, varscan2
- TULP4 | c.1280G>C p.R427T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65579458, COSV65579643; called by muse, mutect2, varscan2
- UBE4B | c.2336G>C p.R779T (on ENST00000343090 / NM_001105562.3; = p.R650T on NM_006048.5) | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53539276; called by muse, mutect2, varscan2
- UBQLNL | c.291C>G p.Y97* | Nonsense Mutation (SNP) | VAF 72/99 reads (73%) | catalogued as COSV66494198; called by muse, mutect2, varscan2
- UFD1 | c.292-1G>A p.X98_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as COSV54252650; called by muse, mutect2, varscan2
- UGT1A3 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.332); catalogued as COSV59395657; called by muse, mutect2, varscan2
- UHMK1 | c.562-2A>T p.X188_splice | Splice Site (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56420971; called by muse, varscan2
- UNC45B | c.2088C>A p.H696Q | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52092618, COSV52099357; called by muse, mutect2, varscan2
- UNC50 | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760419044, COSV53849698; called by muse, mutect2, varscan2
- USP40 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV52486466; called by muse, mutect2, varscan2
- USP7 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV61216752; called by muse, mutect2, varscan2
- UTP15 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57147205; called by muse, mutect2, varscan2
- VCAN | c.5169G>C p.K1723N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV54110798, COSV54113488, COSV54117868; called by muse, mutect2, varscan2
- VGLL3 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV67354085; called by muse, mutect2, varscan2
- VPS13D | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV50645059, COSV50667124; called by muse, mutect2, varscan2
- VWA3B | c.2446G>T p.A816S | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV68245640; called by muse, mutect2, varscan2
- WARS1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs764466208, COSV59926982; called by muse, mutect2, varscan2
- WDR17 | c.2359C>A p.L787M | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54580683; called by muse, mutect2, varscan2
- WDR35 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55604328, COSV55605689; called by muse, mutect2, varscan2
- WNT7B | c.298+1G>T p.X100_splice | Splice Site (SNP) | VAF 15/20 reads (75%) | catalogued as COSV59751809; called by muse, mutect2
- WNT8B | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100649001; called by muse, mutect2, varscan2
- XK | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV66120688; called by muse, mutect2, varscan2
- ZBED2 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.065); catalogued as COSV51920724; called by muse, mutect2, varscan2
- ZBTB26 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV65403811; called by muse, mutect2, varscan2
- ZC3H12B | c.1921A>T p.S641C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59050639; called by muse, mutect2, varscan2
- ZFC3H1 | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1465924720, COSV101110488; called by muse, mutect2, varscan2
- ZFPM2 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101023257, COSV65875262; called by muse, mutect2, varscan2
- ZIC3 | c.770A>G p.D257G | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV54976154; called by muse, mutect2, varscan2
- ZIM2 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55643404; called by muse, mutect2, varscan2
- ZMIZ2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV54810235; called by muse, mutect2, varscan2
- ZNF154 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs773669101, COSV70745360; called by muse, mutect2, varscan2
- ZNF208 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV68103515, COSV68110991; called by muse, mutect2, varscan2
- ZNF335 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59816775, COSV59819460; called by muse, mutect2, varscan2
- ZNF341 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61010554; called by muse, mutect2, varscan2
- ZNF358 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | catalogued as COSV51179112; called by muse, mutect2, varscan2
- ZNF440 | c.1226C>G p.S409* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as COSV58372077; called by muse, mutect2, varscan2
- ZNF441 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63540586; called by muse, mutect2, varscan2
- ZNF473 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54524584; called by muse, mutect2, varscan2
- ZNF536 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62831340; called by muse, mutect2, varscan2
- ZNF574 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs756335478, COSV55905907; called by muse, mutect2, varscan2
- ZNF639 | c.653A>C p.D218A | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV58384030; called by muse, mutect2, varscan2
- ZNF804A | c.2148A>C p.L716F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV56464587; called by muse, mutect2, varscan2
- ZNF91 | c.2801G>A p.G934E | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV56090352; called by muse, mutect2
- ZNRF4 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.169); catalogued as rs767996579, COSV55775838; called by muse, mutect2, varscan2
- ZP4 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV63911448, COSV63913131; called by muse, mutect2, varscan2
- ZP4 | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV63913136; called by muse, mutect2, varscan2
- ADAMTS2 | c.1513del p.A505Rfs*49 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- CDC5L | c.1160del p.L387Cfs*9 | Frame Shift Del (DEL) | VAF 83/164 reads (51%) | called by mutect2, pindel, varscan2
- CDK13 | c.2170del p.D724Ifs*8 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- CNOT6L | c.39_41del p.P14del (on ENST00000504123 / NM_001286790.2; = p.P9del on NM_144571.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- CTSF | c.1439_1440del p.S480Cfs*16 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2314G>T p.V772F | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DDX52 | c.1413del p.L471Ffs*2 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- ELMO1 | c.448dup p.C150Lfs*15 | Frame Shift Ins (INS) | VAF 21/114 reads (18%) | called by mutect2, pindel, varscan2
- EVC2 | c.2617del p.A873Pfs*18 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel, varscan2
- FCGBP | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FLRT2 | c.940dup p.C314Lfs*2 | Frame Shift Ins (INS) | VAF 70/286 reads (24%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GRM1 | c.3013del p.A1005Pfs*26 | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | called by mutect2, pindel*, varscan2
- HYDIN | c.4878C>A p.F1626L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, varscan2
- IGHM | c.1074del p.A359Rfs*20 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by pindel, varscan2
- IL33 | c.547del p.M183Wfs*2 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- ITGAE | c.116dup p.S39Rfs*38 | Frame Shift Ins (INS) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- KCNJ2 | c.932del p.C311Sfs*6 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel*, varscan2
- LGI2 | c.1181dup p.V395Gfs*9 | Frame Shift Ins (INS) | VAF 76/247 reads (31%) | called by mutect2, pindel, varscan2
- LRRC7 | c.4381del p.R1461Gfs*9 (on ENST00000651989 / NM_001370785.2; = p.R1381Gfs*9 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, varscan2
- LYZL6 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NSD1 | c.6494_6500del p.D2165Afs*127 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- OR8G2P | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- PLD2 | c.325_327dup p.E109dup | In Frame Ins (INS) | VAF 37/205 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.338); called by muse, mutect2
- PTPRC | c.670_671insGTG p.S224delinsCA | In Frame Ins (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel*, varscan2
- SETBP1 | c.935dup p.P313Afs*27 | Frame Shift Ins (INS) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- SLC24A2 | c.1145dup p.A383Gfs*16 | Frame Shift Ins (INS) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- STX5 | c.822_826del p.Q274Hfs*2 | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | called by mutect2, pindel, varscan2
- TAAR2 | c.179del p.G60Afs*5 (on ENST00000367931 / NM_001033080.1; = p.G15Afs*5 on NM_014626.3) | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- TAS1R2 | c.1867_1868delinsA p.G623Sfs*72 | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | called by pindel, varscan2*
- TP53I11 | c.489del p.L164Sfs*84 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel*, varscan2
- TRBV30 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- UTRN | c.2791del p.Q931Rfs*4 | Frame Shift Del (DEL) | VAF 53/190 reads (28%) | called by mutect2, pindel, varscan2
- XPR1 | c.665del p.P222Lfs*26 | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- ABCC12 | c.2964C>T p.F988= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV60917008; called by muse, mutect2, varscan2
- ACAD10 | c.135G>C p.V45= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV58161307; called by muse, mutect2, varscan2
- ACOX3 | c.150C>T p.T50= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs760082223, COSV62713313; called by muse, mutect2, varscan2
- ADAM12 | c.2466C>A p.L822= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV64134798; called by muse, mutect2, varscan2
- ADGRB3 | c.1443C>A p.T481= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV65412967; called by muse, mutect2, varscan2
- ADGRG4 | c.3060T>C p.N1020= | Silent (SNP) | VAF 14/209 reads (7%) | catalogued as rs1239990571, COSV54963873; called by muse, mutect2
- ALAS2 | c.501T>A p.T167= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV58192677; called by muse, mutect2, varscan2
- ALPK3 | c.1788G>A p.G596= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1044264701, COSV51938053; called by muse, mutect2, varscan2
- AMER3 | c.1872A>T p.T624= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV58469059; called by muse, mutect2, varscan2
- ANKRD2 | c.345C>A p.L115= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV53969304; called by muse, mutect2, varscan2
- APOM | c.566G>A p.*189= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as COSV101023018, COSV65524677; called by muse, mutect2, varscan2
- ARFGEF2 | c.432G>T p.L144= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV64214307; called by muse, mutect2, varscan2
- ARL11 | c.252C>A p.L84= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV56291934; called by muse, mutect2, varscan2
- ASCC3 | c.5085C>T p.F1695= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs745682031, COSV64972141; called by muse, mutect2, varscan2
- ASTN1 | c.2418G>T p.L806= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV56079797; called by muse, mutect2, varscan2
- ASXL3 | c.1003C>A p.R335= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs765803411, COSV52471978, COSV52475965, COSV99324572; called by mutect2, varscan2
- ATP6V1F | c.291A>T p.P97= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV50800222; called by muse, mutect2, varscan2
- ATP8B4 | c.2820C>A p.L940= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV52721711; called by muse, mutect2, varscan2
- ATXN2 | c.1578A>C p.S526= (on ENST00000550104; = p.S366= on NM_002973.4) | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as COSV66485385; called by muse, mutect2, varscan2
- AXDND1 | c.2277C>A p.S759= | Silent (SNP) | VAF 53/212 reads (25%) | catalogued as rs923137377, COSV62646704; called by muse, mutect2, varscan2
- BCL11B | c.2448G>T p.R816= (on ENST00000357195 / NM_001282237.2; = p.R745= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV61738196; called by muse, mutect2, varscan2
- BCL2L13 | c.435T>A p.V145= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100456241; called by muse, mutect2, varscan2
- BCL6B | c.1227G>A p.E409= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV53429083; called by muse, mutect2, varscan2
- BSCL2 | c.57C>T p.V19= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs746722132, COSV53655453; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTBD3 | c.1218C>T p.F406= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV54778420; called by muse, mutect2, varscan2
- CACNB1 | c.870T>A p.I290= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV59999843; called by muse, mutect2, varscan2
- CACNB2 | c.768C>A p.P256= (on ENST00000324631 / NM_201596.3; = p.P201= on NM_000724.4) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99994130; called by muse, mutect2, varscan2
- CAMLG | c.594T>C p.L198= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV51805499; called by muse, mutect2, varscan2
- CASZ1 | c.2193G>T p.L731= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV59739781; called by muse, mutect2, varscan2
- CC2D1A | c.1977C>A p.L659= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100528429; called by muse, mutect2
- CCNL2 | c.981G>A p.S327= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs367995434; called by muse, mutect2, varscan2
- CCT6B | c.1227T>A p.P409= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as rs780871687, COSV58491100; called by muse, mutect2, varscan2
- CD22 | c.168C>T p.F56= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as COSV50062055; called by muse, mutect2, varscan2
- CD70 | c.81C>A p.V27= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV55566911; called by muse, mutect2, varscan2
- CD8A | c.237G>A p.K79= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV99374385; called by muse, mutect2, varscan2
- CDS2 | c.934C>T p.L312= | Silent (SNP) | VAF 158/211 reads (75%) | catalogued as COSV66897332; called by muse, mutect2, varscan2
- CHRM2 | c.168C>A p.T56= | Silent (SNP) | VAF 63/104 reads (61%) | catalogued as COSV100280749, COSV57781043; called by muse, mutect2, varscan2
- CHRM2 | c.403C>A p.R135= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs748172206, COSV57765468, COSV57787501; called by muse, mutect2, varscan2
- CLUL1 | c.985C>T p.L329= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV58113099; called by muse, mutect2, varscan2
- CMSS1 | c.600G>A p.L200= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV70440357; called by muse, mutect2
- CNTN2 | c.3090G>A p.A1030= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs772810010, COSV59352094; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPS1 | c.738C>T p.P246= | Silent (SNP) | VAF 49/239 reads (21%) | catalogued as COSV51820416; called by muse, mutect2, varscan2
- CPS1 | c.2940C>A p.G980= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV51820435; called by muse, mutect2, varscan2
- CSMD1 | c.5568C>A p.S1856= (on ENST00000520002; = p.S1855= on NM_033225.6) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100146907, COSV59342215; called by muse, mutect2, varscan2
- CTDP1 | c.327G>C p.V109= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV50007704; called by muse, mutect2, varscan2
- CTSE | c.34C>T p.L12= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100733625; called by muse, mutect2, varscan2
- CTSE | c.33C>T p.L11= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs782097606, COSV100733622; called by muse, mutect2, varscan2
- CWC22 | c.1683A>G p.P561= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV55426465, COSV55431668; called by muse, mutect2, varscan2
- DDX10 | c.1005G>A p.R335= | Silent (SNP) | VAF 57/101 reads (56%) | catalogued as COSV59438470; called by muse, mutect2, varscan2
- DDX58 | c.1710C>T p.F570= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV65884344; called by muse, mutect2, varscan2
- DIP2A | c.4605G>T p.V1535= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV59484358; called by muse, mutect2, varscan2
- DLK1 | c.1131G>A p.E377= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs1295669953, COSV57992990; called by muse, mutect2, varscan2
- DNAJC14 | c.138T>G p.A46= | Silent (SNP) | VAF 96/203 reads (47%) | catalogued as COSV57913985; called by muse, mutect2, varscan2
- EDA | c.303C>A p.P101= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV58878365; called by muse, mutect2, varscan2
- EPS8L2 | c.1509C>T p.F503= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV59349750; called by muse, mutect2, varscan2
- ERC1 | c.2883G>A p.L961= (on ENST00000360905 / NM_178040.4; = p.L933= on NM_178039.4) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV61693214; called by muse, mutect2, varscan2
- FAM104B | c.96C>A p.I32= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs1173910992, COSV100146042, COSV59778902; called by muse, mutect2, varscan2
- FAM149A | c.1596G>T p.P532= (on ENST00000356371 / NM_001367768.2; = p.P241= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 70/96 reads (73%) | catalogued as COSV57029577, COSV57030228; called by muse, mutect2, varscan2
- FAM81B | c.258C>A p.T86= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV51985926; called by muse, mutect2, varscan2
- FAM83G | c.840G>T p.T280= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV58760892; called by muse, mutect2, varscan2
- FAT3 | c.9423T>C p.Y3141= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV53157067, COSV99963151; called by muse, mutect2, varscan2
- FBH1 | c.2817G>A p.L939= (on ENST00000362091 / NM_178150.3; = p.L990= on NM_032807.4) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV62984046; called by muse, mutect2, varscan2
- FBXO15 | c.708A>G p.L236= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs750086635, COSV54047612; called by mutect2, varscan2
- FBXO27 | c.612C>T p.L204= | Silent (SNP) | VAF 137/232 reads (59%) | catalogued as COSV53072967; called by muse, mutect2, varscan2
- FLVCR2 | c.1311C>A p.I437= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs765965107, COSV53160683, COSV53163989; called by muse, mutect2, varscan2
- FZD3 | c.285C>G p.V95= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as COSV53537195; called by muse, mutect2, varscan2
- GATA2 | c.666G>A p.K222= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV62006084; called by muse, mutect2, varscan2
- GLYR1 | c.507G>A p.R169= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV58928630, COSV58929545; called by muse, mutect2, varscan2
- GM2A | c.27C>T p.L9= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs760185979, COSV64095812; called by muse, mutect2, varscan2
- GNAO1 | c.123T>A p.A41= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as COSV52618487; called by muse, mutect2, varscan2
- GPR45 | c.582C>G p.A194= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV51525651; called by muse, mutect2, varscan2
- HAX1 | c.705G>T p.R235= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as COSV55178831; called by muse, mutect2, varscan2
- HECTD4 | c.1677A>G p.S559= | Silent (SNP) | VAF 49/69 reads (71%) | catalogued as rs373751710; called by muse, mutect2, varscan2
126 further variants in this file (0 protein-altering or splice-affecting, 111 silent, 15 other) are not listed here.
